Somatic mutation profile of tumor specimen TARGET-40-PAUJZR-01A (aliquot TARGET-40-PAUJZR-01A-01D) from TARGET case TARGET-40-PAUJZR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 8.4 years (3,075 days).
Specimen TARGET-40-PAUJZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0781e98-a166-4a15-84a4-8a3dae3755d2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAUJZR-10A (Blood Derived Normal), aliquot TARGET-40-PAUJZR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e0c5dd6-951f-49ce-b75f-e281dee4c255

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM186A | c.3425T>A p.V1142D | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1260098076; called by muse, varscan2
- FCHSD2 | c.1193T>C p.I398T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs771186144; called by muse, mutect2, varscan2
- MUC4 | c.12197A>C p.H4066P | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs545076894; called by muse, varscan2
- MUC4 | c.5839T>A p.S1947T | Missense Mutation (SNP) | VAF 94/744 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.159); catalogued as rs76803161; called by muse, varscan2
- MUC4 | c.5127G>C p.Q1709H | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as rs78921372; called by muse, varscan2
- SEMA3F | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs749081279, COSV50030659; called by muse, mutect2
- PCLO | c.7385T>C p.L2462P | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MUC4 | c.7404C>T p.T2468= | Silent (SNP) | VAF 74/488 reads (15%) | catalogued as rs564034908; called by muse, varscan2
- PC | c.63C>T p.T21= | Silent (SNP) | VAF 64/139 reads (46%) | catalogued as rs1283060530; called by muse, mutect2, varscan2
- PCNX2 | c.1692G>A p.E564= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV99266519; called by muse, mutect2, varscan2
- SMCR8 | c.213C>G p.P71= | Silent (SNP) | VAF 92/1086 reads (8%) | catalogued as rs775415893; called by muse, mutect2
- HSPA8 | c.*10G>A | 3'UTR (SNP) | VAF 11/89 reads (12%) | catalogued as rs913944272; called by muse, mutect2
